Somatic mutation profile of tumor specimen C3N-00750-02 (aliquot CPT0265110006) from CPTAC case C3N-00750, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G2.
Specimen C3N-00750-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cdef100-b2ad-496f-b9a5-f8f4013e8070.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00750-31 (Blood Derived Normal), aliquot CPT0264020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f468897-49ae-4cc5-98dd-0b82d302f8af

The open-access MAF lists 143 somatic variants for this specimen: 97 protein-altering or splice-affecting, 33 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 33, Intron 5, Frame Shift Del 5, RNA 4, 3'UTR 3, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 131/479 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 157/373 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 144/241 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- ABCA2 | c.1249G>A p.A417T (on ENST00000614293; = p.A387T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as rs761731074; called by muse, mutect2, varscan2
- ABCC6 | c.3725C>T p.T1242M | Missense Mutation (SNP) | VAF 162/389 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs141449320; called by muse, mutect2, varscan2
- AP1B1 | c.2737C>T p.R913W | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs760486493; called by muse, mutect2, varscan2
- ASXL3 | c.6347C>T p.A2116V | Missense Mutation (SNP) | VAF 108/198 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as rs757112357, COSV52466903, COSV52470266; called by muse, mutect2, varscan2
- BCAS3 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 65/517 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754690134, COSV66785044; called by muse, mutect2, varscan2
- CBS | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs758712880, CM115665, COSV61444538, COSV61446652; ClinVar: uncertain significance; called by mutect2, varscan2
- CCDC85A | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.381); catalogued as rs187792610, COSV68150980; called by muse, mutect2, varscan2
- DDX3X | c.688A>C p.T230P (on ENST00000399959; = p.T231P on NM_001356.5) | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV67864609; called by muse, mutect2, varscan2
- EPB41L3 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1397759498; called by muse, mutect2, varscan2
- FLII | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs373517807; called by muse, mutect2, varscan2
- GJA8 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 98/691 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1553242805; called by muse, mutect2, varscan2
- GRK7 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767011044, COSV99380342; called by muse, mutect2
- GRM3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64471156; called by muse, mutect2, varscan2
- HPSE2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 62/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373235110, COSV65184516; called by muse, mutect2, varscan2
- INSL4 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1341022546; called by muse, mutect2, varscan2
- INTS3 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 232/358 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1558001898, COSV59681741; called by muse, mutect2, varscan2
- JARID2 | c.1752C>A p.F584L | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59193895; called by muse, varscan2
- JPH3 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322374578, COSV52471144; called by muse, mutect2, varscan2
- KDR | c.1865A>G p.N622S | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs1316722582, COSV55762469; called by muse, mutect2, varscan2
- KLHDC7B | c.1018G>C p.E340Q (on ENST00000395676; = p.E981Q on NM_138433.5) | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV67464512, COSV67465067; called by muse, mutect2, varscan2
- KLHL1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as COSV100917181; called by muse, mutect2, varscan2
- MGAM | c.4489G>A p.V1497M | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs201533344; called by muse, mutect2, varscan2
- MPP7 | c.1499A>C p.N500T | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as rs774077109; called by muse, mutect2, varscan2
- NLRP7 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV60175633; called by muse, mutect2, varscan2
- NOTCH1 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs752071569, COSV53039096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUTM2A | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 404/1303 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV101095719; called by muse, mutect2, varscan2
- PARD6G | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 164/460 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV62062497; called by muse, mutect2
- PGR | c.2695C>G p.R899G | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54799223, COSV54801600; called by muse, mutect2, varscan2
- PTEN | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 79/149 reads (53%) | catalogued as rs1554897262, COSV64311473; called by muse, mutect2, varscan2
- PTEN | c.388del p.R130Efs*4 | Frame Shift Del (DEL) | VAF 142/625 reads (23%) | catalogued as CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; called by mutect2, pindel, varscan2
- RPL10A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs1389343176; called by muse, mutect2, varscan2
- SEC31A | c.2693C>T p.P898L (on ENST00000355196 / NM_001318120.1; = p.P859L on NM_016211.4) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs1183397869; called by muse, mutect2, varscan2
- SFMBT2 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs145593608; called by muse, mutect2, varscan2
- SNX1 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56039803; called by muse, mutect2, varscan2
- SOGA3 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV64106640; called by muse, mutect2, varscan2
- STAT5B | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 117/404 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs776285574; ClinVar: uncertain significance; called by muse, varscan2
- TBX5 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs942514260; called by muse, mutect2, varscan2
- TMEM125 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs779925429, COSV71326916; called by muse, mutect2, varscan2
- TMEM94 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1326078250; called by muse, mutect2
- TNRC6B | c.3905del p.S1302Ffs*16 (on ENST00000454349 / NM_001162501.2; = p.S1192Ffs*16 on NM_015088.3) | Frame Shift Del (DEL) | VAF 34/246 reads (14%) | catalogued as COSV100109870; called by mutect2, pindel, varscan2
- TSEN34 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 213/531 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55477617; called by muse, mutect2, varscan2
- TUBA3C | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV68028632; called by muse, mutect2
- YTHDF2 | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs764504425, COSV100863591; called by muse, mutect2, varscan2
- ZMIZ1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57902618; called by muse, mutect2
- ZNF454 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs774761220; called by muse, mutect2, varscan2
- ZNF541 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54546884; called by muse, mutect2, varscan2
- ZNF605 | c.1794C>A p.F598L | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs751808016; called by muse, mutect2, varscan2
- ABCA7 | c.4923C>G p.F1641L | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAD8 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 126/430 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4755-2A>G p.X1585_splice | Splice Site (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- ADCY1 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- AKAP12 | c.2747C>A p.A916D | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- APEH | c.2008A>G p.M670V | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATCAY | c.645C>T p.F215= | Splice Region (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- CACNA1D | c.6193G>T p.V2065F (on ENST00000350061 / NM_001128840.3; = p.V2085F on NM_000720.4) | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC34 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- CCDC34 | c.700del p.E234Kfs*7 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | called by pindel, varscan2
- CCDC34 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 32/120 reads (27%) | called by muse, varscan2
- CDK16 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CXCL12 | c.211T>G p.C71G | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHB1 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCFC1 | c.5379+1G>T p.X1793_splice | Splice Site (SNP) | VAF 113/496 reads (23%) | called by muse, mutect2, varscan2
- HOOK1 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- IGKV2-30 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 106/886 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ITGB8 | c.696_697del p.N233Hfs*3 | Frame Shift Del (DEL) | VAF 38/268 reads (14%) | called by pindel, varscan2
- KAT14 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 106/388 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF2A | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- KLHDC7B | c.764G>C p.G255A (on ENST00000395676; = p.G896A on NM_138433.5) | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.065); called by muse, varscan2
- KMT2D | c.12623dup p.N4208Kfs*126 | Frame Shift Ins (INS) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- KMT5A | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 178/418 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MGAM | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MTDH | c.483+2dup p.X161_splice | Splice Site (INS) | VAF 32/241 reads (13%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OGT | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PGR | c.2486_2487insTT p.I830* | Frame Shift Ins (INS) | VAF 67/218 reads (31%) | called by mutect2, pindel, varscan2
- PHYHIPL | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 121/186 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHM2 | c.2429G>T p.R810L | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB26 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RNF39 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RNF44 | c.66C>G p.F22L | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSRP1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SEC63 | c.1347A>G p.I449M | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SKOR2 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SLC4A2 | c.502_503del p.R168Dfs*46 | Frame Shift Del (DEL) | VAF 44/444 reads (10%) | called by pindel, varscan2
- SPTLC3 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SYNE2 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 61/212 reads (29%) | called by muse, mutect2, varscan2
- TEP1 | c.3183G>C p.K1061N | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIE1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TNPO3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 225/425 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRIP11 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- USP51 | c.1997A>G p.Y666C | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNT6 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- XCR1 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIC2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA2 | c.2472G>A p.A824= (on ENST00000614293; = p.A794= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as rs373098079, COSV55807601; called by muse, mutect2, varscan2
- ADGRG4 | c.6612T>C p.F2204= | Silent (SNP) | VAF 71/201 reads (35%) | catalogued as COSV99794470; called by muse, mutect2, varscan2
- ALG5 | c.51C>A p.A17= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs759530016; called by muse, mutect2, varscan2
- CAPN5 | c.960C>T p.I320= (on ENST00000456580; = p.I280= on NM_004055.5) | Silent (SNP) | VAF 92/157 reads (59%) | called by muse, mutect2, varscan2
- CARD14 | c.1860C>T p.Y620= | Silent (SNP) | VAF 39/401 reads (10%) | catalogued as rs148265488; called by muse, mutect2
- CLEC4G | c.30C>T p.G10= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs367931064; called by muse, mutect2, varscan2
- COL4A2 | c.5121G>A p.V1707= | Silent (SNP) | VAF 53/288 reads (18%) | catalogued as rs947260890; called by muse, mutect2, varscan2
- DOCK5 | c.1314G>A p.L438= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2
- DOK1 | c.81C>G p.A27= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs777723974, COSV99284203; called by muse, mutect2, varscan2
- FRMPD4 | c.1455C>T p.H485= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs752586467, COSV101043400, COSV66212334; called by mutect2, varscan2
- GPC6 | c.555C>T p.D185= | Silent (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2, varscan2
- HECW1 | c.1815G>A p.T605= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV67821821; called by muse, mutect2, varscan2
- LGALS3BP | c.1635C>T p.P545= | Silent (SNP) | VAF 44/524 reads (8%) | called by muse, mutect2
- LRTM2 | c.264C>T p.F88= | Silent (SNP) | VAF 138/310 reads (45%) | catalogued as rs368418051; called by muse, mutect2, varscan2
- MAB21L1 | c.961C>T p.L321= | Silent (SNP) | VAF 92/232 reads (40%) | called by muse, mutect2, varscan2
- MAN1A2 | c.1152A>G p.T384= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs749191816; called by muse, mutect2, varscan2
- NEFL | c.411G>A p.A137= | Silent (SNP) | VAF 62/652 reads (10%) | catalogued as rs1444396530, COSV99647970; called by muse, mutect2
- OAF | c.777C>T p.P259= | Silent (SNP) | VAF 40/257 reads (16%) | catalogued as rs757029515; called by muse, mutect2, varscan2
- PARP12 | c.990C>T p.I330= | Silent (SNP) | VAF 24/166 reads (14%) | called by mutect2, varscan2
- PCDH8 | c.744C>T p.G248= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV58812758; called by muse, mutect2, varscan2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 122/856 reads (14%) | catalogued as COSV50858046; called by muse, mutect2, varscan2
- PLEKHG1 | c.970C>T p.L324= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- PRAG1 | c.1956C>T p.H652= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as rs771265409; called by muse, mutect2, varscan2
- RGSL1 | c.810C>A p.L270= | Silent (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- SERPINB6 | c.198A>G p.G66= (on ENST00000612421 / NM_001271823.2; = p.G47= on NM_004568.6) | Silent (SNP) | VAF 146/327 reads (45%) | catalogued as rs1366353418; called by muse, mutect2, varscan2
- SH3GL2 | c.741T>A p.A247= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- SHFL | c.180C>T p.N60= | Silent (SNP) | VAF 58/264 reads (22%) | catalogued as rs368279366, COSV53467411; called by muse, mutect2, varscan2
- TANK | c.1033C>T p.L345= | Silent (SNP) | VAF 190/694 reads (27%) | catalogued as COSV52048279; called by muse, mutect2, varscan2
- TNFRSF19 | c.192C>T p.F64= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs145815290; called by muse, varscan2
- TNR | c.1455G>T p.V485= | Silent (SNP) | VAF 49/587 reads (8%) | catalogued as rs909768890; called by muse, mutect2
- TRIM46 | c.1689G>A p.L563= | Silent (SNP) | VAF 709/1005 reads (71%) | catalogued as rs1345901406; called by muse, mutect2, varscan2
- TRMT112 | c.201G>T p.P67= | Silent (SNP) | VAF 103/262 reads (39%) | catalogued as COSV50005976; called by muse, mutect2, varscan2
- WDR61 | c.792G>A p.R264= | Silent (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- AC136628.2 | n.664C>T | RNA (SNP) | VAF 150/418 reads (36%) | catalogued as rs1225466294; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505168 del TTTT | 5'Flank (DEL) | VAF 20/123 reads (16%) | catalogued as rs752288826; called by mutect2, pindel, varscan2
- ASB9P1 | n.52G>C | RNA (SNP) | VAF 87/201 reads (43%) | catalogued as rs1466536681; called by muse, mutect2, varscan2
- ATP6AP1L | n.1322G>C | RNA (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- C11orf21 | c.54-86G>A | Intron (SNP) | VAF 241/453 reads (53%) | called by muse, mutect2, varscan2
- KLHL2 | c.1754-664A>C | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- LINC00615 | n.314G>T | RNA (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- MTRNR2L10 | c.*9G>C | 3'UTR (SNP) | VAF 59/152 reads (39%) | catalogued as rs753966712; called by muse, mutect2, varscan2
- PDPN | c.67+1457A>T | Intron (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- PNCK | c.*246G>A | 3'UTR (SNP) | VAF 77/150 reads (51%) | catalogued as rs1194849789, COSV61744830; called by muse, mutect2, varscan2
- SLC10A7 | c.183+1933C>T | Intron (SNP) | VAF 25/110 reads (23%) | catalogued as rs1376286046; called by muse, mutect2, varscan2
- SMARCAD1 | c.*549A>G | 3'UTR (SNP) | VAF 143/316 reads (45%) | called by muse, mutect2, varscan2
- USH1C | c.1285-2682G>C | Intron (SNP) | VAF 60/345 reads (17%) | called by muse, mutect2, varscan2
